Somatic mutation profile of tumor specimen TCGA-EE-A17Y-06A (aliquot TCGA-EE-A17Y-06A-11D-A196-08) from TCGA case TCGA-EE-A17Y, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 70.6 years (25,788 days).
Specimen TCGA-EE-A17Y-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0acc2f69-17cf-4269-bc00-f9e6cc162998.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A17Y-10B (Blood Derived Normal), aliquot TCGA-EE-A17Y-10B-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4212a297-9bc7-4e88-8d23-88823ab9940d

The open-access MAF lists 196 somatic variants for this specimen: 127 protein-altering or splice-affecting, 64 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 64, Nonsense Mutation 9, Intron 4, Splice Region 2, Splice Site 2, Frame Shift Del 2, Frame Shift Ins 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AXL | c.1550G>A p.G517D (on ENST00000301178 / NM_021913.5; = p.G508D on NM_001699.6) | Missense Mutation (SNP) | VAF 31/77 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56573323; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- GALNS | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559063128, CM166236, CM950532, COSV51939841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GDAP1 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as rs1554548334, CM094563, COSV99619688; ClinVar: pathogenic; called by mutect2, varscan2
- AC092143.1 | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | catalogued as COSV59248754; called by muse, mutect2, varscan2
- ACTRT1 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV64419900; called by muse, mutect2, varscan2
- ADAM7 | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 58/228 reads (25%) | catalogued as rs773090797, COSV51545272; called by muse, varscan2
- ADAM7 | c.410A>G p.D137G | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.763); catalogued as COSV51545283; called by muse, mutect2, varscan2
- ADGRG4 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV54953326; called by muse, mutect2, varscan2
- AFM | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV56921706; called by muse, mutect2, varscan2
- AGFG1 | c.1354C>T p.Q452* | Nonsense Mutation (SNP) | VAF 20/115 reads (17%) | catalogued as COSV59514260; called by muse, mutect2, varscan2
- ALG10 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 70/245 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762214045, COSV56791818; called by muse, mutect2, varscan2
- ALPK2 | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV64494350; called by muse, mutect2, varscan2
- ARFGEF3 | c.2663C>T p.S888F | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs1304092912, COSV52457768; called by muse, mutect2, varscan2
- ATP10D | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV56708062, COSV56711858; called by muse, mutect2, varscan2
- B3GNT4 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as rs769085783, COSV57336999; called by muse, mutect2, varscan2
- B4GALNT2 | c.218A>G p.K73R | Missense Mutation (SNP) | VAF 93/311 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.828); catalogued as COSV55927844; called by muse, mutect2, varscan2
- B4GALNT4 | c.1096-1G>A p.X366_splice | Splice Site (SNP) | VAF 8/32 reads (25%) | catalogued as rs1160490278, COSV100327694; called by muse, mutect2
- B4GALNT4 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100327695, COSV57327221; called by muse, mutect2
- BEST3 | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV58304571; called by muse, mutect2, varscan2
- BOC | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs751100635, COSV56351162; called by mutect2, varscan2
- BRCA2 | c.4792C>T p.L1598F | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV66460382; called by muse, mutect2, varscan2
- C12orf42 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV59388941; called by muse, mutect2, varscan2
- C7 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV57470310, COSV57477578; called by muse, mutect2
- CDH7 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV59892340; called by muse, mutect2, varscan2
- CDK17 | c.851T>C p.I284T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.481); catalogued as COSV54132457; called by muse, mutect2, varscan2
- CERKL | c.1193C>T p.S398F (on ENST00000339098 / NM_001030311.2; = p.S372F on NM_201548.5) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV59208159; called by muse, mutect2, varscan2
- CFHR3 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV100807643; called by mutect2, varscan2
- CLEC4M | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV50218844; called by muse, mutect2, varscan2
- COL3A1 | c.2267G>A p.G756E | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM940304, COSV58589341; called by muse, mutect2
- COL4A4 | c.2749C>T p.P917S | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1237546505, COSV61630230; called by muse, mutect2, varscan2
- COL9A1 | c.2441G>A p.G814E | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100295051; called by muse, mutect2, varscan2
- COMMD3 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 56/106 reads (53%) | catalogued as rs1212890647, COSV100936430; called by muse, mutect2, varscan2
- CYP1A2 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 94/337 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as rs751760377, COSV100673912; called by muse, mutect2, varscan2
- CYP1A2 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 95/336 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV59659574; called by muse, mutect2, varscan2
- CYP2A13 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57837066; called by muse, mutect2, varscan2
- DNAH5 | c.1642C>T p.H548Y | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs778487272, COSV54245951; called by muse, mutect2, varscan2
- DNAH7 | c.9521C>T p.S3174F | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56780194; called by muse, varscan2
- DNAH7 | c.3063G>A p.M1021I | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV56780202; called by muse, mutect2, varscan2
- EDEM2 | c.1565C>T p.S522L | Missense Mutation (SNP) | VAF 104/307 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs146309337; called by muse, mutect2, varscan2
- FAAP100 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.218); catalogued as COSV59887099; called by muse, varscan2
- FSTL5 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.795); catalogued as COSV60221418; called by muse, mutect2, varscan2
- GABRB2 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV50925747; called by muse, mutect2, varscan2
- GALNT13 | c.1656G>A p.M552I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV101223425; called by muse, mutect2, varscan2
- GPC5 | c.588G>A p.M196I | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.158); catalogued as COSV65621934; called by muse, mutect2, varscan2
- HES1 | c.133A>T p.R45* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV51685448; called by mutect2, varscan2
- IGF1 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV61034081; called by muse, mutect2, varscan2
- IL23R | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61375850; called by muse, mutect2, varscan2
- IL5RA | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.144); catalogued as rs1181103089, COSV56521545; called by muse, mutect2, varscan2
- KALRN | c.8914C>T p.P2972S (on ENST00000360013 / NM_001024660.4; = p.P1275S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as COSV52262729; called by muse, mutect2, varscan2
- KAT14 | c.614T>C p.V205A | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.07); catalogued as COSV66608937; called by muse, mutect2, varscan2
- KCNB2 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.018); catalogued as COSV73052306; called by muse, mutect2, varscan2
- KCNG1 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65370212; called by muse, mutect2
- KCNQ3 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66479333; called by muse, mutect2, varscan2
- KLHDC3 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.138); catalogued as rs867239280, COSV55064189; called by muse, mutect2
- KLHL17 | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV58533108; called by muse, mutect2, varscan2
- LHX4 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.124); catalogued as COSV55377541; called by muse, mutect2, varscan2
- LONP2 | c.1265C>G p.P422R | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53525316; called by muse, mutect2, varscan2
- LRP5 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV53721881; called by muse, mutect2, varscan2
- ME1 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63839037; called by mutect2, varscan2
- MICAL2 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99817812; called by muse, mutect2, varscan2
- MMP27 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52782295; called by muse, mutect2, varscan2
- MTMR9 | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.955); catalogued as COSV99644398; called by muse, mutect2, varscan2
- MYH8 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 117/397 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67969995; called by muse, mutect2, varscan2
- MYLK | c.4048C>A p.L1350M | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60619218; called by mutect2, varscan2
- MYPOP | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.023); catalogued as COSV56194201, COSV56194788; called by muse, mutect2, varscan2
- NCR1 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as COSV52558013; called by muse, mutect2, varscan2
- NISCH | c.2136G>A p.W712* | Nonsense Mutation (SNP) | VAF 27/47 reads (57%) | catalogued as COSV61901756; called by muse, mutect2, varscan2
- NMUR2 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as COSV99677032; called by muse, mutect2, varscan2
- NUP58 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 108/399 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs1225856933, COSV67751941; called by muse, mutect2, varscan2
- OGDHL | c.120C>G p.F40L | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV65104099; called by muse, mutect2, varscan2
- OR5L1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV61735085; called by muse, mutect2, varscan2
- OR6V1 | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV69237604; called by muse, mutect2, varscan2
- PAK5 | c.64C>T p.H22Y | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62035400; called by muse, mutect2, varscan2
- PARP14 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV72111757; called by muse, mutect2, varscan2
- PCDHB12 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as COSV53396364, COSV53399976; called by muse, mutect2, varscan2
- PCDHB14 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.152); catalogued as rs1352087240, COSV53390572; called by muse, mutect2, varscan2
- PCED1B | c.976C>T p.H326Y | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71395573; called by muse, mutect2, varscan2
- PDE1C | c.1766G>A p.G589E | Missense Mutation (SNP) | VAF 75/287 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV58525288; called by muse, mutect2, varscan2
- PEBP4 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56464831; called by muse, varscan2
- PHF3 | c.2982T>A p.N994K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.029); catalogued as COSV50334092; called by muse, mutect2, varscan2
- PIAS2 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs750182425, COSV61344721; called by muse, mutect2, varscan2
- PROC | c.1041C>A p.S347R | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.35); catalogued as COSV52167801, COSV52168794; called by muse, mutect2
- PSD2 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.192); catalogued as COSV51207792; called by muse, mutect2, varscan2
- PTPRB | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54246170, COSV99719144; called by muse, mutect2, varscan2
- RASSF9 | c.997C>T p.H333Y | Missense Mutation (SNP) | VAF 97/336 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV63435434, COSV63435569; called by muse, mutect2, varscan2
- RNF17 | c.4522C>T p.P1508S | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV55048553; called by muse, mutect2, varscan2
- RYR1 | c.11062G>A p.E3688K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.257); catalogued as rs1471770778, COSV62107329; called by mutect2, varscan2
- SAV1 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV61205185, COSV61205544; called by mutect2, varscan2
- SCN7A | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as COSV69272954; called by muse, mutect2, varscan2
- SELP | c.7A>C p.N3H | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.357); catalogued as COSV55256654; called by muse, mutect2
- SERPINB4 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as COSV61984025; called by muse, varscan2
- SERPING1 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.225); catalogued as rs145436911, COSV99558206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC16A14 | c.1166A>G p.N389S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); catalogued as COSV54620707; called by muse, mutect2, varscan2
- SLC26A7 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52587999; called by muse, mutect2, varscan2
- SLC2A12 | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV51602052; called by muse, mutect2, varscan2
- SLC43A1 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as COSV53560851; called by muse, mutect2, varscan2
- SLC9C2 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as COSV62948470; called by muse, mutect2, varscan2
- SLIT3 | c.2975G>A p.R992Q | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs769550253, COSV60615061; called by muse, mutect2, varscan2
- SMYD5 | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 17/29 reads (59%) | catalogued as rs1300551619, COSV50265522; called by muse, mutect2, varscan2
- SNTG1 | c.1038G>A p.K346= | Splice Region (SNP) | VAF 19/61 reads (31%) | catalogued as COSV99384448; called by muse, mutect2, varscan2
- SNTG1 | c.1038+1G>A p.X346_splice | Splice Site (SNP) | VAF 18/59 reads (31%) | catalogued as COSV99384451; called by muse, mutect2, varscan2
- SRRM2 | c.6169C>T p.R2057C | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs144781002; called by muse, mutect2, varscan2
- STYXL2 | c.657G>A p.G219= | Splice Region (SNP) | VAF 15/41 reads (37%) | catalogued as COSV54808935; called by muse, mutect2
- TAF1C | c.2386C>T p.Q796* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as rs938886973, COSV58988389; called by muse, mutect2, varscan2
- TAF7L | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV61257030, COSV61257807; called by muse, mutect2, varscan2
- TFCP2 | c.1357T>C p.C453R | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV56935307; called by muse, mutect2, varscan2
- TLR7 | c.1988G>A p.S663N | Missense Mutation (SNP) | VAF 78/112 reads (70%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV66125248; called by muse, mutect2, varscan2
- TMEM97 | c.218A>G p.E73G | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56879379; called by muse, mutect2, varscan2
- TRPC4 | c.2597C>T p.S866F (on ENST00000379705 / NM_016179.4; = p.S871F on NM_003306.3) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as rs1555247540, COSV59013343; called by muse, mutect2, varscan2
- TSC2 | c.89C>A p.S30Y | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.235); catalogued as COSV54594044; called by mutect2, varscan2
- TTC31 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 57/98 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV99282210; called by muse, mutect2, varscan2
- TTN | c.11386G>A p.E3796K (on ENST00000591111; = p.E3750K on NM_003319.4) | Missense Mutation (SNP) | VAF 70/139 reads (50%) | catalogued as rs866724412, COSV100618971; called by muse, varscan2
- TTN | c.11360G>A p.S3787N (on ENST00000591111; = p.S3741N on NM_003319.4) | Missense Mutation (SNP) | VAF 21/107 reads (20%) | catalogued as COSV59950405; called by muse, varscan2
- TTN | c.3304G>A p.G1102R (on ENST00000591111; = p.G1056R on NM_003319.4) | Missense Mutation (SNP) | VAF 39/93 reads (42%) | PolyPhen benign (0.021); catalogued as rs1016142990, COSV59979446; called by muse, mutect2, varscan2
- WDR20 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV100085187, COSV54474518; called by muse, mutect2, varscan2
- WNT8A | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV100843062; called by muse, mutect2, varscan2
- XKR3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs752777395, COSV58887583; called by muse, mutect2, varscan2
- ZHX1 | c.1852G>C p.E618Q | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52878395; called by muse, mutect2, varscan2
- ZNF347 | c.1997C>T p.S666L | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV61967459; called by muse, mutect2, varscan2
- ZNF490 | c.1572T>G p.H524Q | Missense Mutation (SNP) | VAF 57/229 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV61008894; called by muse, mutect2, varscan2
- ZNF711 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV52157879; called by muse, mutect2, varscan2
- AQR | c.598del p.I200Lfs*34 | Frame Shift Del (DEL) | VAF 47/202 reads (23%) | called by mutect2, pindel, varscan2
- ASAH2 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 87/151 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC60 | c.957_961del p.R319Sfs*14 | Frame Shift Del (DEL) | VAF 5/58 reads (9%) | called by mutect2, pindel
- PRAMEF20 | c.1419T>G p.C473W | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2
- RYR2 | c.10203dup p.V3402Sfs*10 | Frame Shift Ins (INS) | VAF 12/26 reads (46%) | called by mutect2, varscan2
- ADAM28 | c.2160G>A p.K720= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as rs766981119, COSV56104190; called by muse, mutect2, varscan2
- ADNP2 | c.1854C>T p.A618= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV51541713; called by muse, mutect2, varscan2
- AP002748.5 | c.768G>A p.L256= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV59151203; called by muse, mutect2, varscan2
- AQP11 | c.427C>T p.L143= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV57993088; called by muse, mutect2, varscan2
- AXIN1 | c.1164C>T p.F388= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs566061517, COSV51986803; called by mutect2, varscan2
- CCR3 | c.249C>T p.F83= | Silent (SNP) | VAF 85/175 reads (49%) | catalogued as rs774437865, COSV62463443; called by muse, mutect2, varscan2
- CFTR | c.3807C>T p.I1269= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs1800129, COSV50045167; ClinVar: likely benign; called by muse, mutect2, varscan2
- CILP2 | c.3150C>T p.A1050= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV52279165; called by muse, mutect2
- COL22A1 | c.4254C>T p.I1418= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV57354610; called by muse, mutect2, varscan2
- COPA | c.3432C>T p.I1144= | Silent (SNP) | VAF 73/268 reads (27%) | catalogued as COSV54107982; called by muse, mutect2, varscan2
- CR2 | c.417G>A p.G139= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as rs763604504, COSV65509235; called by muse, mutect2, varscan2
- CUX1 | c.1668C>T p.I556= | Silent (SNP) | VAF 64/216 reads (30%) | catalogued as COSV52911194; called by muse, mutect2, varscan2
- CYP4F12 | c.171G>A p.R57= | Silent (SNP) | VAF 45/145 reads (31%) | catalogued as COSV61172385; called by muse, mutect2, varscan2
- DMXL2 | c.1323T>C p.G441= | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as COSV51853773; called by muse, mutect2
- DNAH5 | c.11934G>A p.P3978= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs370543923; ClinVar: likely benign; called by muse, mutect2, varscan2
- DOK7 | c.1356G>A p.R452= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV60773466; called by muse, mutect2, varscan2
- ENGASE | c.1743C>T p.L581= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV56137293; called by muse, mutect2, varscan2
- F7 | c.24C>T p.L8= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV60647550; called by muse, mutect2, varscan2
- FABP6 | c.309G>A p.E103= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV67436896, COSV67437587; called by muse, varscan2
- FAM210A | c.150C>T p.G50= | Silent (SNP) | VAF 23/156 reads (15%) | catalogued as COSV59185727; called by muse, mutect2, varscan2
- FLNB | c.7461C>T p.S2487= | Silent (SNP) | VAF 67/152 reads (44%) | catalogued as COSV55891969; called by muse, mutect2, varscan2
- FMO1 | c.1005C>T p.F335= | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as rs764096863, COSV61445178; called by muse, mutect2, varscan2
- FYB1 | c.534G>A p.G178= | Silent (SNP) | VAF 31/121 reads (26%) | catalogued as COSV60954096; called by muse, mutect2, varscan2
- FZD10 | c.1719C>T p.I573= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs775122719, COSV57475292; called by muse, mutect2, varscan2
- GBF1 | c.4884C>T p.F1628= (on ENST00000369983 / NM_001377137.1; = p.F1627= on NM_004193.3) | Silent (SNP) | VAF 68/119 reads (57%) | catalogued as COSV64148162; called by muse, mutect2, varscan2
- GDAP1 | c.702C>T p.G234= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV99619685; called by muse, mutect2, varscan2
- IL19 | c.178C>T p.L60= | Silent (SNP) | VAF 49/139 reads (35%) | catalogued as COSV54284481; called by muse, mutect2, varscan2
- IQCH | c.2256C>T p.V752= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV60058663; called by mutect2, varscan2
- KCNC3 | c.1293C>T p.F431= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs752090228, COSV65386742; called by muse, mutect2, varscan2
- KLC3 | c.555G>A p.R185= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV67269949; called by muse, mutect2, varscan2
- LIMK2 | c.942C>T p.S314= | Silent (SNP) | VAF 39/152 reads (26%) | catalogued as rs909140455, COSV59183994; called by muse, mutect2, varscan2
- LIPE | c.21A>C p.S7= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV54924901; called by muse, mutect2, varscan2
- LRRC15 | c.483G>A p.L161= | Silent (SNP) | VAF 85/162 reads (52%) | catalogued as rs1453203861, COSV61651224; called by muse, mutect2, varscan2
- MICAL2 | c.615C>T p.L205= | Silent (SNP) | VAF 65/159 reads (41%) | catalogued as rs766948713, COSV99817809; called by muse, mutect2, varscan2
- MORC2 | c.2071C>T p.L691= (on ENST00000397641 / NM_001303256.3; = p.L629= on NM_014941.3) | Silent (SNP) | VAF 68/140 reads (49%) | catalogued as COSV53201681; called by muse, mutect2, varscan2
- MUC16 | c.10356C>T p.I3452= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs748833016, COSV101197706, COSV67485841; called by muse, mutect2, varscan2
- MYH6 | c.2247C>T p.S749= | Silent (SNP) | VAF 39/81 reads (48%) | catalogued as COSV62453665; called by muse, mutect2, varscan2
- MYO5B | c.858C>T p.F286= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV53228088; called by muse, mutect2, varscan2
- MYO7A | c.4710C>T p.F1570= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV68686606; called by muse, mutect2, varscan2
- MYRF | c.1341C>T p.I447= (on ENST00000278836 / NM_001127392.3; = p.I438= on NM_013279.4) | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs774713037, COSV53889412; called by mutect2, varscan2
- NLRP14 | c.2136C>T p.I712= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV100205173; called by muse, mutect2, varscan2
- NMUR2 | c.9G>A p.G3= | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as rs1244419239, COSV99676564; called by muse, mutect2, varscan2
- NWD1 | c.1518C>T p.L506= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV60349201; called by muse, mutect2, varscan2
- OR4F6 | c.810C>T p.F270= | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as rs373176011; called by muse, mutect2, varscan2
- OR51M1 | c.168C>T p.F56= | Silent (SNP) | VAF 17/143 reads (12%) | catalogued as COSV60785255; called by muse, mutect2, varscan2
- OR5R1 | c.186C>T p.F62= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV56573331; called by muse, mutect2, varscan2
- PHF20 | c.1950C>T p.F650= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as rs752496261, COSV59185576; called by muse, mutect2, varscan2
- PIGL | c.39C>G p.V13= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV51990518; called by muse, mutect2, varscan2
- PRR4 | c.297C>T p.H99= | Silent (SNP) | VAF 78/225 reads (35%) | catalogued as COSV57392561; called by muse, mutect2, varscan2
- PRTG | c.2892C>T p.I964= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV66840041; called by muse, mutect2, varscan2
- RASGRP1 | c.186G>A p.L62= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV60367085; called by muse, mutect2, varscan2
- RPS6KA4 | c.2055C>T p.L685= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV53705901; called by muse, mutect2, varscan2
- SIRPG | c.24C>T p.P8= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as rs1326384035, COSV53809692; called by muse, mutect2, varscan2
- SLC27A1 | c.240C>A p.R80= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99393456; called by muse, mutect2, varscan2
- SLC5A3 | c.294C>T p.I98= | Silent (SNP) | VAF 287/534 reads (54%) | catalogued as COSV62972658; called by muse, mutect2, varscan2
- SLC6A5 | c.2112C>T p.T704= | Silent (SNP) | VAF 60/130 reads (46%) | catalogued as COSV54231144; called by muse, mutect2, varscan2
- SRRM2 | c.6168C>T p.S2056= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV99241544; called by muse, mutect2, varscan2
- TTC31 | c.786C>T p.P262= | Silent (SNP) | VAF 55/91 reads (60%) | catalogued as COSV99282234; called by muse, mutect2, varscan2
- TTN | c.20250A>G p.V6750= (on ENST00000591111; = p.V5823= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV60274483; called by muse, mutect2, varscan2
- TXNDC11 | c.1389C>T p.S463= (on ENST00000356957 / NM_001303447.2; = p.S436= on NM_015914.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV51601569; called by muse, mutect2, varscan2
- UGT1A3 | c.225C>T p.F75= | Silent (SNP) | VAF 28/133 reads (21%) | catalogued as COSV59395259; called by muse, mutect2, varscan2
- UNC45B | c.1845G>A p.K615= | Silent (SNP) | VAF 68/221 reads (31%) | catalogued as COSV52096150; called by muse, mutect2, varscan2
- VWC2 | c.705A>T p.P235= | Silent (SNP) | VAF 58/192 reads (30%) | catalogued as COSV61490330; called by muse, mutect2, varscan2
- ZNF582 | c.450C>T p.P150= | Silent (SNP) | VAF 45/141 reads (32%) | catalogued as COSV56733423; called by muse, mutect2, varscan2
- ADGRE4P | n.1262C>T | RNA (SNP) | VAF 30/110 reads (27%) | called by muse, mutect2, varscan2
- AL109984.1 | n.186+4905G>A | Intron (SNP) | VAF 48/164 reads (29%) | catalogued as rs1472824664, COSV63754278; called by muse, mutect2, varscan2
- CEP128 | c.1209+937A>G | Intron (SNP) | VAF 5/11 reads (45%) | catalogued as COSV99383418; called by muse, mutect2, varscan2
- EIF4A1 | c.996+58C>T | Intron (SNP) | VAF 15/52 reads (29%) | catalogued as rs1555568281, COSV99549040; called by muse, mutect2, varscan2
- TTN | c.34264+4787G>A | Intron (SNP) | VAF 50/283 reads (18%) | catalogued as COSV100618970; called by muse, mutect2, varscan2
